Somatic mutation profile of tumor specimen TCGA-ET-A3DV-01A (aliquot TCGA-ET-A3DV-01A-12D-A202-08) from TCGA case TCGA-ET-A3DV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 68.2 years (24,905 days).
Specimen TCGA-ET-A3DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd9828c4-7a05-4c29-b400-2ad072351eac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3DV-11A (Solid Tissue Normal), aliquot TCGA-ET-A3DV-11A-11D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d7fdf0f-e0dc-4339-8c00-93b10abe4123

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GZMM | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs373840917; called by muse, mutect2, varscan2
- NOX5 | c.2270G>T p.G757V | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV52986643; called by muse, mutect2, varscan2
- SHLD2 | c.114A>T p.K38N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV53953713; called by muse, mutect2, varscan2
- TP73 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60699833; called by muse, mutect2, varscan2
- ZNF341 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.499); catalogued as rs567905770, COSV61007362; called by muse, mutect2, varscan2
- CACNG8 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- IRX6 | c.1249C>T p.L417= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV51859717; called by muse, mutect2
